Somatic mutation profile of tumor specimen TCGA-39-5039-01A (aliquot TCGA-39-5039-01A-01D-1441-08) from TCGA case TCGA-39-5039, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.1 years (27,781 days).
Specimen TCGA-39-5039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1382c70a-a8f9-4ac2-b955-8a74c7f53a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5039-11A (Solid Tissue Normal), aliquot TCGA-39-5039-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abe0247c-e729-49ec-aaa5-63e6bf7d5227

The open-access MAF lists 183 somatic variants for this specimen: 139 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 41, Nonsense Mutation 10, Splice Site 5, Frame Shift Del 5, Splice Region 4, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs121964977, CM042068, CM1510184, COSV58679212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 17/128 reads (13%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AC127029.3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs753333968, COSV60110802; called by muse, mutect2, varscan2
- ADAMTS12 | c.101C>A p.P34Q | Missense Mutation (SNP) | VAF 67/419 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs201411671, COSV100711316, COSV61276392; called by muse, mutect2, varscan2
- ADAMTS18 | c.2218G>T p.V740F | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs199599392, COSV51421376; called by muse, mutect2, varscan2
- ADAMTS18 | c.1656G>C p.R552S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV51421382; called by muse, mutect2
- ADCY2 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57874641; called by muse, mutect2, varscan2
- ADGRE1 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV51679096, COSV51679698; called by muse, mutect2, varscan2
- ADGRL3 | c.1424C>T p.S475L (on ENST00000506720 / NM_001322402.2; = p.S407L on NM_015236.6) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1454556522, COSV72271753; called by muse, mutect2, varscan2
- AGL | c.3044A>G p.Y1015C | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs750686172, COSV54057097; called by muse, mutect2, varscan2
- AGMO | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.348); catalogued as COSV61121545; called by muse, mutect2, varscan2
- AKAP9 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.762); catalogued as COSV62355193; called by muse, mutect2, varscan2
- AKT2 | c.285G>A p.E95= | Splice Region (SNP) | VAF 10/170 reads (6%) | catalogued as COSV60907980, COSV60909942; called by muse, mutect2
- AOC1 | c.1549C>A p.R517S | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710852, COSV62868280; called by muse, mutect2, varscan2
- ARID1A | c.1583A>T p.Q528L | Missense Mutation (SNP) | VAF 42/313 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as COSV61385974; called by muse, mutect2, varscan2
- ASAH2 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV61484262; called by muse, mutect2, varscan2
- ASL | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs200853731, COSV59189183; called by muse, varscan2
- ASPSCR1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60716307; called by muse, mutect2
- ATP11A | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 72/268 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs150693839; called by muse, mutect2, varscan2
- ATP2B3 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as rs782653125, COSV54845320, COSV54846951; called by muse, mutect2, varscan2
- ATP8B1 | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs758746529, COSV52172880, COSV52179087; called by muse, mutect2, varscan2
- ATR | c.2864A>G p.Q955R | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV63390552; called by muse, mutect2, varscan2
- ATR | c.2746G>C p.A916P | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV63390560; called by muse, mutect2
- BNC1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61758780; called by muse, mutect2, varscan2
- BRINP3 | c.1848C>A p.N616K | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV66525972, COSV66537136; called by muse, mutect2
- C3orf20 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 42/310 reads (14%) | catalogued as COSV53788427, COSV53789370; called by muse, mutect2, varscan2
- CECR2 | c.4058C>A p.S1353* (on ENST00000342247 / NM_001290047.2; = p.S1169* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 62/203 reads (31%) | catalogued as COSV52838462, COSV52846482; called by muse, mutect2, varscan2
- CENPE | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54387860; called by muse, mutect2, varscan2
- CEP164 | c.1824G>T p.R608S | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV54045316; called by muse, mutect2, varscan2
- CEP290 | c.1864G>T p.D622Y | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV58354921, COSV58355474; called by muse, mutect2, varscan2
- CHST12 | c.617A>G p.H206R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1314072205, COSV51677457; called by muse, mutect2, varscan2
- CLIP4 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV60751763; called by muse, mutect2, varscan2
- CLSTN2 | c.2839G>T p.E947* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV71724012; called by muse, mutect2, varscan2
- CNTNAP5 | c.2622G>T p.W874C | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755061930, COSV70506190; called by muse, mutect2, varscan2
- COL1A2 | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.417); catalogued as COSV51964044; called by muse, mutect2, varscan2
- COL21A1 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1259722031, COSV55175750; called by muse, mutect2, varscan2
- CPB1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51576226; called by muse, varscan2
- CRP | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 59/512 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814386; called by muse, mutect2, varscan2
- CRP | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 58/516 reads (11%) | catalogued as COSV54814395; called by muse, mutect2, varscan2
- CSMD3 | c.10434A>T p.R3478S (on ENST00000297405 / NM_001363185.1; = p.R3309S on NM_052900.3) | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV52283558; called by muse, mutect2, varscan2
- CTNND2 | c.104T>A p.L35* | Nonsense Mutation (SNP) | VAF 23/207 reads (11%) | catalogued as COSV58877109, COSV58916835; called by muse, mutect2, varscan2
- DDA1 | c.137-2A>T p.X46_splice | Splice Site (SNP) | VAF 124/660 reads (19%) | catalogued as COSV63290037; called by muse, mutect2, varscan2
- DMD | c.6946A>G p.I2316V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58941644; called by muse, mutect2, varscan2
- DNAH5 | c.3787A>G p.I1263V | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as COSV54245756; called by muse, mutect2, varscan2
- DNAH9 | c.6343G>T p.V2115F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1490781302, COSV52370136; called by muse, mutect2, varscan2
- ERAP1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV57090726; called by muse, mutect2, varscan2
- FRMPD1 | c.4597C>G p.Q1533E | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.69); catalogued as COSV100899660, COSV66702201; called by muse, mutect2, varscan2
- FRS2 | c.1070C>G p.P357R | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54728743; called by muse, mutect2, varscan2
- FUBP1 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936771; called by muse, mutect2, varscan2
- FUBP1 | c.454G>T p.G152* | Nonsense Mutation (SNP) | VAF 25/130 reads (19%) | catalogued as COSV53936801; called by muse, mutect2, varscan2
- GFPT1 | c.1106-2A>T p.X369_splice (on ENST00000357308 / NM_001244710.2; = p.X351_splice on NM_002056.4) | Splice Site (SNP) | VAF 28/237 reads (12%) | catalogued as COSV61949979; called by muse, mutect2, varscan2
- GPC6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760150200, COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GPR26 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV52935983; called by muse, mutect2
- HAT1 | c.1053C>G p.Y351* | Nonsense Mutation (SNP) | VAF 28/178 reads (16%) | catalogued as COSV51361941, COSV51365007; called by muse, mutect2, varscan2
- HHIPL2 | c.1117A>T p.K373* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as COSV58567084; called by muse, mutect2, varscan2
- HSD3B1 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141328314, COSV52492600; called by muse, mutect2, varscan2
- HSD3B1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs1424469384, COSV52491867; called by muse, mutect2, varscan2
- HTR1A | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.134); catalogued as COSV60502436; called by muse, mutect2, varscan2
- IGF2R | c.953G>C p.C318S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63631899; called by muse, mutect2, varscan2
- IGLV4-69 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs560151357; called by muse, mutect2, varscan2
- IGSF22 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV60037599; called by muse, mutect2
- INO80D | c.1954G>T p.A652S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68959841; called by muse, mutect2
- IQCN | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs767600410, COSV66576764; called by muse, mutect2, varscan2
- ITFG2 | c.1216A>T p.S406C | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57390710; called by muse, mutect2, varscan2
- KEL | c.1902G>T p.E634D | Missense Mutation (SNP) | VAF 38/275 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV62337183; called by muse, mutect2, varscan2
- KIF5A | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54051576, COSV54056394; called by muse, mutect2
- LCK | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV60740522, COSV60742219; called by muse, mutect2, varscan2
- LMBR1 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1416198782, COSV100626529; called by muse, mutect2, varscan2
- LONP2 | c.799A>T p.N267Y | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV53525286; called by muse, mutect2, varscan2
- LRP1B | c.2077A>C p.K693Q | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as COSV67261161; called by muse, mutect2, varscan2
- MMP19 | c.200C>A p.P67Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV59452742; called by muse, mutect2
- MRTFA | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as rs762204984, COSV62935914; called by muse, mutect2, varscan2
- MRTFA | c.1179A>G p.P393= | Splice Region (SNP) | VAF 14/55 reads (25%) | catalogued as rs1395853591, COSV62935919; called by mutect2, varscan2
- MUC5B | c.10490C>G p.A3497G | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV71594635; called by muse, mutect2, varscan2
- NCOR2 | c.3290C>T p.P1097L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.805); catalogued as rs530717643, COSV62302532; called by muse, mutect2, varscan2
- NECAP1 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764080699, COSV60250272; called by muse, mutect2
- NKIRAS1 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV60669329; called by muse, mutect2, varscan2
- NLGN4X | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs979850927, COSV52032162, COSV52034398; called by muse, mutect2, varscan2
- NRIP3 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV58470945; called by muse, mutect2
- NSMAF | c.1036T>C p.S346P | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV50697356; called by muse, mutect2, varscan2
- NYNRIN | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV66844369; called by muse, mutect2, varscan2
- OPN1SW | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV50822907; called by muse, mutect2, varscan2
- OR10Q1 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.434); catalogued as COSV57471575; called by muse, mutect2, varscan2
- OR52N5 | c.718T>A p.S240T | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV57699333; called by muse, mutect2
- ORC1 | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as COSV57121651, COSV57122868; called by muse, mutect2
- PATL1 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.618); catalogued as COSV55692111; called by muse, mutect2, varscan2
- PCDHGA10 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV54010026; called by muse, mutect2, varscan2
- PCED1B | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71395571; called by muse, mutect2
- PDE1C | c.1335G>T p.M445I | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as COSV58525202; called by muse, mutect2, varscan2
- PDZD2 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV56869466; called by muse, mutect2, varscan2
- PIGR | c.2285A>G p.Q762R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62904790; called by muse, mutect2, varscan2
- PKN3 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.454); catalogued as COSV52577023; called by muse, mutect2
- PLK3 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 77/497 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as COSV59500797; called by muse, mutect2, varscan2
- PPM1K | c.857A>T p.H286L | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55797447; called by muse, mutect2, varscan2
- PREX2 | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55761399, COSV55764900; called by muse, mutect2, varscan2
- PROKR2 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54088634; called by muse, mutect2, varscan2
- PTPN22 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100703424, COSV63086201; called by muse, mutect2, varscan2
- PTPRB | c.2768G>A p.S923N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs775764884, COSV54235144; called by muse, mutect2, varscan2
- PTPRK | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1439315253, COSV63893491, COSV63893497; called by muse, mutect2, varscan2
- RIMS2 | c.2721A>G p.S907= (on ENST00000666250 / NM_001348490.2; = p.S715= on NM_014677.5 and 7 other RefSeq transcripts) | Splice Region (SNP) | VAF 29/196 reads (15%) | catalogued as COSV99176102; called by muse, mutect2, varscan2
- RPH3A | c.823G>T p.A275S (on ENST00000389385 / NM_001143854.2; = p.A271S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.255); catalogued as COSV66992503; called by muse, mutect2
- RPS6KA5 | c.1029A>C p.L343F | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV56224479; called by muse, mutect2, varscan2
- SHOX | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1443010174, COSV61862081; called by muse, mutect2
- SLC13A1 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52015688, COSV52017201; called by muse, mutect2
- SLC20A1 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55612494; called by muse, mutect2, varscan2
- SLC39A11 | c.306+1G>T p.X102_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | catalogued as rs1293837088, COSV55299138; called by muse, mutect2
- SLC4A10 | c.3217G>A p.G1073R (on ENST00000446997 / NM_001354461.2; = p.G1043R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV55794962; called by muse, mutect2
- SMUG1 | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV54540233; called by muse, mutect2
- SORBS3 | c.1994G>T p.G665V | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53554421; called by muse, mutect2, varscan2
- SSTR1 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV57457343; called by muse, mutect2, varscan2
- SYMPK | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); catalogued as COSV55614849; called by muse, mutect2
- TAL1 | c.479T>C p.M160T | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV53748177; called by muse, mutect2, varscan2
- TBC1D32 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51551526; called by muse, mutect2, varscan2
- TECRL | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV67089816; called by muse, mutect2, varscan2
- THBS3 | c.1279C>G p.H427D | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV64250590; called by muse, mutect2, varscan2
- TM9SF4 | c.1604G>T p.G535V | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54110450; called by muse, mutect2, varscan2
- TMPRSS15 | c.211A>T p.N71Y | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV53046721; called by muse, mutect2, varscan2
- TRIP11 | c.958A>G p.K320E | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50949026; called by muse, mutect2
- TRPC4 | c.273C>A p.S91R | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.329); catalogued as COSV59013190; called by muse, mutect2, varscan2
- TTN | c.74246C>A p.P24749Q (on ENST00000591111; = p.P17325Q on NM_003319.4) | Missense Mutation (SNP) | VAF 34/223 reads (15%) | PolyPhen probably damaging (0.999); catalogued as COSV60272652; called by muse, mutect2, varscan2
- TTN | c.19727A>T p.E6576V (on ENST00000591111; = p.E5649V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | PolyPhen possibly damaging (0.529); catalogued as COSV60272687; called by muse, mutect2
- UNC13C | c.5342C>G p.S1781* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52912221; called by muse, mutect2
- VAMP7 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV52902668; called by muse, mutect2, varscan2
- WDR17 | c.2619G>T p.Q873H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV54581241; called by muse, mutect2
- XIRP2 | c.6049A>G p.T2017A (on ENST00000628543; = p.T2192A on NM_152381.6) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54726750; called by muse, mutect2, varscan2
- ZC3H3 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV52793918; called by muse, mutect2, varscan2
- ZFHX4 | c.4904G>A p.G1635E | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV51488274; called by muse, mutect2
- ZFP64 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as COSV53798534, COSV53802918; called by muse, mutect2, varscan2
- ZNF2 | c.1156G>A p.E386K (on ENST00000611147 / NM_001291605.2; = p.E373K on NM_021088.4) | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as rs372113014; called by muse, mutect2, varscan2
- ZNF208 | c.1910A>G p.Y637C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV68111284; called by muse, varscan2
- CHD3 | c.3895-3_3895-1del p.X1299_splice | Splice Site (DEL) | VAF 19/118 reads (16%) | called by mutect2, pindel, varscan2
- COLEC12 | c.447del p.R149Sfs*5 | Frame Shift Del (DEL) | VAF 22/157 reads (14%) | called by mutect2, pindel, varscan2
- DEFB123 | c.36del p.L13Sfs*5 | Frame Shift Del (DEL) | VAF 80/610 reads (13%) | called by mutect2, pindel*, varscan2
- GUF1 | c.507+1del | Frame Shift Del (DEL) | VAF 47/452 reads (10%) | called by mutect2, pindel, varscan2
- KLHL24 | c.82del p.E28Kfs*7 | Frame Shift Del (DEL) | VAF 25/159 reads (16%) | called by mutect2, varscan2
- LILRB3 | c.845C>G p.T282S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.135); called by muse, mutect2
- M1AP | c.237del p.F79Lfs*4 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | called by mutect2, pindel, varscan2
- MRC1 | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 48/662 reads (7%) | called by muse, mutect2
- NCF2 | c.714-3_720del p.X238_splice | Splice Site (DEL) | VAF 42/486 reads (9%) | called by mutect2, pindel
- ADAMTS16 | c.2655C>T p.C885= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs749886441, COSV57003255; called by muse, mutect2
- ADGRG4 | c.7008C>T p.A2336= | Silent (SNP) | VAF 41/220 reads (19%) | catalogued as COSV54964220; called by muse, mutect2, varscan2
- ARNTL2 | c.1137A>G p.G379= | Silent (SNP) | VAF 28/188 reads (15%) | catalogued as COSV53828340; called by muse, mutect2, varscan2
- ATP2B3 | c.2877G>C p.A959= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs781883776, COSV54848861, COSV54858164; called by muse, mutect2, varscan2
- C7 | c.2427C>T p.N809= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs746573247, COSV57479161; called by muse, mutect2, varscan2
- CDH11 | c.1197C>T p.G399= | Silent (SNP) | VAF 28/234 reads (12%) | catalogued as rs1163957916, COSV51773357; called by muse, mutect2, varscan2
- CDH12 | c.810C>G p.P270= | Silent (SNP) | VAF 51/292 reads (17%) | catalogued as COSV101201497, COSV66438116; called by muse, mutect2, varscan2
- CDKN2A | c.276C>T p.D92= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV58711113; called by muse, varscan2
- CEACAM18 | c.30G>T p.L10= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV67283759; called by muse, mutect2
- CECR2 | c.4059A>T p.S1353= (on ENST00000342247 / NM_001290047.2; = p.S1169= on NM_001290046.1) | Silent (SNP) | VAF 61/203 reads (30%) | catalogued as rs553870318, COSV52846495; called by muse, mutect2, varscan2
- CHRM2 | c.1086C>A p.A362= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV57781682; called by muse, mutect2, varscan2
- CTNNA3 | c.2520G>T p.G840= | Silent (SNP) | VAF 36/256 reads (14%) | catalogued as COSV65521826, COSV65528414; called by muse, mutect2, varscan2
- CTSO | c.345G>A p.R115= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs771018128, COSV70809526; called by muse, mutect2, varscan2
- DHRS4L2 | c.600G>C p.L200= | Silent (SNP) | VAF 19/328 reads (6%) | catalogued as COSV58730887; called by muse, mutect2
- EPCAM | c.867C>G p.S289= | Silent (SNP) | VAF 56/411 reads (14%) | catalogued as COSV55394261; called by muse, mutect2, varscan2
- FREM1 | c.4764T>C p.T1588= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV66528370; called by muse, mutect2, varscan2
- FSTL1 | c.585A>T p.G195= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV55236167; called by muse, mutect2, varscan2
- GPHN | c.1089C>T p.D363= (on ENST00000315266 / NM_001377519.1; = p.D396= on NM_020806.5) | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV59490187; called by muse, mutect2, varscan2
- HOXB7 | c.489G>T p.T163= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as COSV53310705, COSV53311841; called by muse, varscan2
- JHY | c.78A>T p.T26= | Silent (SNP) | VAF 12/197 reads (6%) | catalogued as COSV56221180; called by muse, mutect2
- LILRA6 | c.1080G>A p.G360= | Silent (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.21225C>T p.T7075= (on ENST00000372915; = p.T5120= on NM_012090.5) | Silent (SNP) | VAF 36/340 reads (11%) | catalogued as rs200883556, COSV57138030; called by muse, mutect2, varscan2
- MRPL44 | c.615C>T p.S205= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs1203438199, COSV51314398; called by muse, mutect2, varscan2
- MUC16 | c.24258A>T p.P8086= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV67485605; called by muse, mutect2, varscan2
- OR4C15 | c.615C>A p.G205= (on ENST00000314644; = p.G151= on NM_001001920.2) | Silent (SNP) | VAF 20/195 reads (10%) | catalogued as rs763191657, COSV100115932, COSV58954929; called by muse, mutect2, varscan2
- OR52N5 | c.267T>C p.N89= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as COSV57699339; called by muse, mutect2
- OR5M8 | c.417G>T p.V139= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV59116634; called by muse, mutect2, varscan2
- PRKG1 | c.625C>A p.R209= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV64790217, COSV64806218; called by muse, mutect2
- RASSF8 | c.777G>A p.K259= | Silent (SNP) | VAF 11/225 reads (5%) | catalogued as COSV51454961; called by muse, mutect2
- SHOX | c.504G>T p.R168= | Silent (SNP) | VAF 18/191 reads (9%) | catalogued as CD075547, COSV61862090; called by muse, mutect2, varscan2
- SIM1 | c.1293C>T p.D431= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs139715467, COSV53495466; called by muse, mutect2, varscan2
- SLC1A3 | c.78A>G p.T26= | Silent (SNP) | VAF 67/350 reads (19%) | catalogued as rs1323111267, COSV54319277; called by muse, mutect2, varscan2
- SLC2A7 | c.261C>T p.G87= | Silent (SNP) | VAF 38/326 reads (12%) | catalogued as rs749169535, COSV68901240; called by muse, varscan2
- SLC4A4 | c.2598A>G p.E866= (on ENST00000264485 / NM_001098484.3; = p.E822= on NM_003759.4) | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV52634728; called by mutect2, varscan2
- THSD7A | c.3189T>G p.R1063= | Silent (SNP) | VAF 62/466 reads (13%) | catalogued as COSV70270480; called by muse, mutect2, varscan2
- TP53TG5 | c.267C>T p.A89= | Silent (SNP) | VAF 31/274 reads (11%) | catalogued as COSV65578100; called by muse, mutect2, varscan2
- UNC79 | c.2667C>A p.P889= (on ENST00000393151 / NM_001346218.2; = p.P712= on NM_020818.5) | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV99828652; called by muse, mutect2, varscan2
- USP26 | c.1071G>A p.K357= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV63709510; called by muse, mutect2, varscan2
- VWCE | c.651C>T p.S217= | Silent (SNP) | VAF 30/348 reads (9%) | catalogued as rs1485888617, COSV57114516; called by muse, mutect2
- WBP11 | c.678C>T p.P226= | Silent (SNP) | VAF 70/521 reads (13%) | catalogued as COSV53764333; called by muse, mutect2, varscan2
- ZNF658 | c.2496G>A p.G832= | Silent (SNP) | VAF 44/233 reads (19%) | catalogued as rs1369071353; called by muse, mutect2, varscan2
- CPLANE1 | c.*5911C>G | 3'UTR (SNP) | VAF 28/216 reads (13%) | catalogued as rs746910113, COSV57070695; called by muse, mutect2, varscan2
- CSH1 | c.456+99G>A | Intron (SNP) | VAF 19/249 reads (8%) | catalogued as COSV100298373; called by muse, mutect2
- TTN | c.10303+2601C>T | Intron (SNP) | VAF 14/116 reads (12%) | catalogued as COSV60272701; called by muse, mutect2, varscan2
